Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AAB1, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AAB1-01A (Primary Tumor).

[page 1 of 3]
Surgery date:

Surgical Pathology

DIAGNOSIS:

D. Head of pancreas, duodenum, and common bile duct; Whipple resection: Invasive grade 3 (of 4) adenocarcinoma with mucinous features is identified forming a diffusely infiltrative mass (4.5 x 2.8 x 2.2 cm) in the region of the pancreatic head and possibly arising from an intraductal papillary mucinous neoplasm (2.0 x 1.5 x 1.5 cm). Tumor extends beyond the pancreas to involve peripancreatic soft tissue and the adjacent duodenal wall. The stomach and gallbladder are uninvolved by tumor. Angiolymphatic invasion is identified. Tumor involves the common bile duct and pancreatic duct. The uncinate margin is involved by tumor. The portal vein groove is negative for tumor. The pancreatic body and common hepatic duct margins are negative for tumor (see parts B and C below); however, the uncinate margin remains positive for tumor. Multiple (7 of 21) peripancreatic lymph nodes are positive for metastatic carcinoma. - Pw TSS - 0% mucinous.

B. Pancreas, body margin, excision: Negative for tumor.

C. Common hepatic duct, margin, excision: Negative for tumor.

A. Lymph node, common hepatic artery, excision: A single (1) lymph node is negative for tumor. Frozen section histologic interpretation performed by:

With available surgical material [AJCCT3N1] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ICD-O-3
Adenocarcinoma NOS 8140/3
Adenocarcinoma mucinous NOS 8480/3
Site: Pancreas head C25.0
7/5/14

Interpreted by:

Report electronically signed by

Transcribed by:

AMENDMENTS: (Previous Signout Date:

Revision Description: Change in wording in part A of diagnosis.

....Original Diagnosis....

D. Head of pancreas, duodenum, and common bile duct; Whipple resection: Invasive grade 3 (of 4) adenocarcinoma with mucinous features is identified forming a diffusely infiltrative mass (4.5 x 2.8 x 2.2 cm) in the region of the pancreatic head and possibly arising from an intraductal papillary mucinous neoplasm (2.0 x 1.5 x 1.5 cm). Tumor extends beyond the pancreas to involve peripancreatic soft tissue and the adjacent duodenal wall. The stomach and gallbladder are uninvolved by tumor. Angiolymphatic invasion is identified. Tumor involves the common bile duct and

[page 2 of 3]
pancreatic duct. The uncinate margin is involved by tumor. The portal vein groove is negative for tumor. Surgical margins, after re-excision (see parts B and C below), are negative for tumor. Multiple (7 of 21) peripancreatic lymph nodes are positive for metastatic carcinoma.

B. Pancreas, body margin, excision: Negative for tumor.

C. Common hepatic duct, margin, excision: Negative for tumor.

A. Lymph node, common hepatic artery, excision: A single (1) lymph node is negative for tumor. Frozen section histologic interpretation performed by:

With available surgical material [AJCCT3N1] (7th edition, 2010).

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Signing Pathologist

GROSS DESCRIPTION:

A. Received fresh labeled "common hepatic artery lymph nodes" is a 2.4 x 1.8 x 0.8 cm lymph node. Lymph node submitted. Grossed by

B. Received fresh labeled "pancreatic body margin with margin up" is a 2.7 x 2.0 x 0.2 cm portion of pancreatic tissue with orientation. Margin submitted. Grossed by

C. Received fresh labeled "common hepatic duct margin" is a 1.0 x 1.0 x 0.3 cm portion of tan-red fibrous tissue without orientation. Margin submitted. Grossed by

D. Received fresh labeled "head of pancreas, duodenum, portion of stomach and jejunum, gallbladder" is a Whipple specimen consistent of 52.0 cm in length portion of duodenum, 7.5 x 6.5 x 5.5 cm portion of pancreas, 7.8 x 3.7 x 1.0 cm gallbladder, and a 20.0 x 7.5 x 3.0 cm portion of stomach. The pancreatic uncinate margin is inked yellow and shaved, the portal vein groove is inked black and submitted perpendicularly. There is a 4.5 x 2.8 x 2.2 cm diffusely infiltrative mass within the pancreatic head at the uncinate margin. The mass extends to peripancreatic soft tissue. A stent is present within the common bile duct. The pancreatic neck contains a 2.0 x 1.5 x 1.5 cm cyst on a side-branch duct. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections submitted. Grossed by

BLOCK SUMMARY:

[page 3 of 3]
Part A: Common hepatic artery lymph nodes

1 Com hepatic artery LN (A1)

Part B: Pancreatic body margin

1 Pancreatic body margin 1

2 Pancreatic body margin 2

Part C: Common hepatic duct margin

1 Common hepatic duct margin

Part D: Head of pancreas, duodenum, portion of stomach, jejunum, and gallbladder

1 Uncinate margin 1

2 Uncinate margin 1

3 Uncinate margin 2

4 Uncinate margin 3

5 Uncinate margin 3

6 Portal vein groove

7 Ampulla

8 Pancreas with bile duct

9 Panc w/ pancreatic duct

10 Pancreas 1

11 Pancreas 2

12 Pancreas 3

13 Pancreas 4

14 Pancreas 5

15 Proximal stomach

16 Gallbladder

17 Pancreatic cyst

18 Peripancreatic LN 4 (D1)

19 Peripancreatic LN 5(D2)

20 Peripancreatic LN 4 (D3)

21 Peripancreatic LN 4 (D4)

22 Peripancreatic LN 3 (D5)

23 Peripancreatic LN 1 (D6)

Source: NCI Genomic Data Commons file ec941c3d-0d5d-40f8-b6c5-fce79f967348 (TCGA-2J-AAB1.224801AA-21C4-4070-B1FE-BAE31CC38318.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).